Somatic mutation profile of tumor specimen C3N-02784-01 (aliquot CPT0206000007) from CPTAC case C3N-02784, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 37.1 years (13,569 days).
Specimen C3N-02784-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09f241a0-d849-4cbf-aa0c-2a6c7ad08028.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02784-71 (Blood Derived Normal), aliquot CPT0206060002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23837ea2-79c1-4b65-bd12-8f447e16a1e9

The open-access MAF lists 309 somatic variants for this specimen: 194 protein-altering or splice-affecting, 87 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 175, Silent 87, Intron 16, Frame Shift Del 6, Nonsense Mutation 6, RNA 4, 3'UTR 4, Splice Region 3, 5'UTR 2, Splice Site 2, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MSH6 | c.742del p.R248Efs*31 | Frame Shift Del (DEL) | VAF 88/178 reads (49%) | catalogued as rs587781691, CM992183, COSV99316661; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 86/147 reads (59%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs121913294, CM074465, CM102472, COSV100911374, COSV64288961, COSV64302184; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1654C>T p.R552* | Nonsense Mutation (SNP) | VAF 46/66 reads (70%) | hotspot (GDC flag); catalogued as rs121913303, CM961229, COSV57297124; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SYN1 | c.1264C>T p.R422* | Nonsense Mutation (SNP) | VAF 125/237 reads (53%) | catalogued as rs757027813; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 258/430 reads (60%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AASS | c.788C>T p.T263M | Missense Mutation (SNP) | VAF 68/257 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs746536178, COSV62789589; called by muse, mutect2, varscan2
- ABCC5 | c.4300G>A p.A1434T | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.005); catalogued as rs553921855, COSV99657448; called by muse, mutect2, varscan2
- ACSM2A | c.1724G>A p.R575H (on ENST00000219054; = p.R496H on NM_001308169.2) | Missense Mutation (SNP) | VAF 92/140 reads (66%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1173954214, COSV54591581; called by muse, mutect2, varscan2
- ADAM12 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 42/74 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs770769845, COSV64106410; called by muse, mutect2, varscan2
- ADAM2 | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 60/94 reads (64%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs766240507; called by muse, mutect2, varscan2
- ADAM22 | c.775G>A p.V259I | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.328); catalogued as rs558399747, COSV55971830; called by muse, mutect2, varscan2
- ADAMTS14 | c.601G>A p.G201R | Missense Mutation (SNP) | VAF 126/206 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1023441102, COSV64607166; called by muse, mutect2, varscan2
- ADAMTS19 | c.3574C>T p.R1192W | Missense Mutation (SNP) | VAF 79/134 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs777662055; called by muse, mutect2, varscan2
- ADARB2 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 139/228 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.359); catalogued as rs1457201824, COSV67223469; called by muse, mutect2, varscan2
- AKAP9 | c.10942C>T p.R3648* (on ENST00000359028; = p.R3624* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 112/367 reads (31%) | catalogued as rs1196642937; called by muse, mutect2, varscan2
- ANK2 | c.5714C>T p.S1905L | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs368566123, COSV52193578; called by muse, mutect2, varscan2
- ANKLE2 | c.2542G>A p.D848N | Missense Mutation (SNP) | VAF 144/271 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs373274502; called by muse, mutect2, varscan2
- ANKS1B | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 198/359 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs370191542; called by muse, mutect2, varscan2
- ARHGAP35 | c.3479C>T p.T1160M | Missense Mutation (SNP) | VAF 142/229 reads (62%) | SIFT tolerated (0.21); PolyPhen benign (0.344); catalogued as rs531784492, COSV101351028; called by muse, mutect2, varscan2
- ARHGDIG | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 148/263 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs963397973; called by muse, mutect2, varscan2
- ATP2B3 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 122/155 reads (79%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as rs782458081; called by muse, mutect2, varscan2
- ATP4A | c.988C>T p.R330W | Missense Mutation (SNP) | VAF 209/337 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs199790968, COSV52869449; called by muse, mutect2, varscan2
- BDKRB2 | c.241G>A p.V81I | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.451); catalogued as rs200683377; called by muse, mutect2, varscan2
- BRD1 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 201/351 reads (57%) | SIFT tolerated (0.98); PolyPhen benign (0.019); catalogued as rs777919210; called by muse, mutect2, varscan2
- C1orf116 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as rs770424183, COSV63943877; called by muse, mutect2
- C2CD3 | c.3548G>A p.R1183H | Missense Mutation (SNP) | VAF 99/176 reads (56%) | SIFT tolerated (0.45); PolyPhen benign (0.107); catalogued as rs200609720; called by muse, mutect2, varscan2
- CACHD1 | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 83/138 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs765213692, COSV51558872; called by muse, mutect2, varscan2
- CACNA1B | c.5456C>T p.A1819V | Missense Mutation (SNP) | VAF 120/215 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.434); catalogued as rs200917554, COSV53113314, COSV53117131; called by muse, mutect2, varscan2
- CCDC60 | c.1412C>T p.P471L | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.999); catalogued as rs1195059657; called by muse, mutect2, varscan2
- CELSR1 | c.6698G>A p.R2233Q | Missense Mutation (SNP) | VAF 86/129 reads (67%) | SIFT tolerated (0.46); PolyPhen benign (0.019); catalogued as rs190281317; called by muse, mutect2, varscan2
- CENPA | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 249/400 reads (62%) | SIFT tolerated (0.21); PolyPhen benign (0.044); catalogued as rs1240955553, COSV51983028; called by muse, mutect2, varscan2
- CFAP20DC | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 137/240 reads (57%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs1486401737; called by muse, mutect2, varscan2
- CFAP47 | c.2581C>T p.R861* | Nonsense Mutation (SNP) | VAF 65/89 reads (73%) | catalogued as COSV52884313; called by muse, mutect2, varscan2
- CHAF1A | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs751874513; called by muse, mutect2, varscan2
- CHTF18 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 286/442 reads (65%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.629); catalogued as rs766620558, COSV50100874; called by muse, mutect2, varscan2
- CNR1 | c.610G>A p.V204M | Missense Mutation (SNP) | VAF 14/370 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1413404443; called by muse, mutect2
- CNTNAP4 | c.2909G>A p.R970H | Missense Mutation (SNP) | VAF 183/314 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755378449; called by muse, varscan2
- CNTNAP4 | c.3526G>A p.V1176M | Missense Mutation (SNP) | VAF 148/244 reads (61%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.626); catalogued as rs773791364, COSV100272214; called by muse, mutect2, varscan2
- COL4A6 | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 147/221 reads (67%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs749725921, COSV57860560; called by muse, mutect2, varscan2
- CRACD | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 53/91 reads (58%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as rs1560535289, COSV51729601; called by muse, mutect2, varscan2
- CRNKL1 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.578); catalogued as rs747114057, COSV66106721; called by muse, varscan2
- CUX1 | c.3049G>A p.V1017I | Missense Mutation (SNP) | VAF 103/255 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.102); catalogued as rs371129117; called by muse, mutect2, varscan2
- DENND5A | c.2764C>T p.R922C | Missense Mutation (SNP) | VAF 82/141 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as rs761947253, COSV60235755; called by muse, mutect2, varscan2
- DEPDC1B | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 37/60 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV54008880; called by muse, mutect2, varscan2
- DHRS4 | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 109/215 reads (51%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs758554224; called by muse, mutect2, varscan2
- DNAH9 | c.7670C>T p.T2557M | Missense Mutation (SNP) | VAF 90/159 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768788141; called by muse, mutect2, varscan2
- DVL2 | c.750G>A p.T250= | Splice Region (SNP) | VAF 93/162 reads (57%) | catalogued as rs753072149, COSV99138906; called by muse, mutect2, varscan2
- EDN2 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs746888124; called by muse, mutect2, varscan2
- ELFN1 | c.2026G>A p.A676T | Missense Mutation (SNP) | VAF 87/193 reads (45%) | SIFT tolerated (0.86); PolyPhen benign (0.006); catalogued as rs1240443026; called by muse, mutect2, varscan2
- EMILIN2 | c.1729C>T p.R577C | Missense Mutation (SNP) | VAF 55/110 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.443); catalogued as rs749622305, COSV54422508, COSV54425099; called by muse, mutect2, varscan2
- ENPP7 | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 157/265 reads (59%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as rs145931726; called by muse, mutect2, varscan2
- EXD2 | c.217C>T p.R73W | Missense Mutation (SNP) | VAF 118/199 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs1215796570; called by muse, mutect2, varscan2
- FAF1 | c.1750G>A p.E584K | Missense Mutation (SNP) | VAF 104/178 reads (58%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs749667431; called by muse, mutect2, varscan2
- FCHO2 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs760036982, COSV55112498; called by muse, mutect2, varscan2
- FSIP1 | c.716C>T p.S239L | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs890757217; called by muse, mutect2, varscan2
- FZD9 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 82/267 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.495); catalogued as COSV60671024; called by muse, mutect2, varscan2
- GFOD2 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 14/328 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.086); catalogued as rs1216081997; called by muse, mutect2
- GMCL2 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 134/219 reads (61%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.003); catalogued as rs756532427; called by muse, mutect2, varscan2
- GPR179 | c.2318G>A p.R773H (on ENST00000621958; = p.R772H on NM_001004334.4) | Missense Mutation (SNP) | VAF 187/355 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs200659752; called by muse, mutect2, varscan2
- GRM8 | c.1856G>A p.R619H | Missense Mutation (SNP) | VAF 144/367 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs916732580, COSV58842144; called by muse, mutect2, varscan2
- HECTD4 | c.8745C>T p.D2915= | Splice Region (SNP) | VAF 121/219 reads (55%) | catalogued as rs367828286; called by muse, mutect2, varscan2
- HIP1 | c.1729C>T p.R577W | Missense Mutation (SNP) | VAF 119/350 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as rs782471782, COSV61185965; called by muse, mutect2, varscan2
- HS6ST3 | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100940150; called by muse, mutect2, varscan2
- HSD11B1L | c.370C>T p.R124* | Nonsense Mutation (SNP) | VAF 15/428 reads (4%) | catalogued as rs983421741; called by muse, mutect2
- HSD11B2 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 347/580 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as rs765709883, COSV52100048; called by muse, mutect2, varscan2
- HSPG2 | c.12328C>T p.R4110C | Missense Mutation (SNP) | VAF 288/447 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as rs766333633, COSV100760752; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IFT140 | c.3704C>T p.T1235M | Missense Mutation (SNP) | VAF 216/351 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs767997025, COSV100794137; called by muse, mutect2, varscan2
- IGLL5 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 511/822 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.067); catalogued as rs192388840; called by muse, mutect2, varscan2
- IGLV1-40 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 98/150 reads (65%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.168); catalogued as rs376636120; called by muse, mutect2, varscan2
- IL31 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 110/196 reads (56%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs755248798, COSV65476579; called by muse, varscan2
- INHBE | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 198/304 reads (65%) | SIFT tolerated (0.2); PolyPhen benign (0.176); catalogued as rs780594253; called by muse, mutect2, varscan2
- INTS5 | c.2546G>A p.R849Q | Missense Mutation (SNP) | VAF 74/100 reads (74%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as rs569085234; called by muse, mutect2, varscan2
- ITGAX | c.2005+1G>A p.X669_splice | Splice Site (SNP) | VAF 89/146 reads (61%) | catalogued as rs753815474; called by muse, mutect2, varscan2
- KNTC1 | c.2398G>A p.V800M | Missense Mutation (SNP) | VAF 113/193 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1163233829, COSV100338414; called by muse, mutect2, varscan2
- KRT36 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 118/198 reads (60%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.615); catalogued as rs1430111265; called by muse, mutect2
- KRT86 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 267/569 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs1372085832; called by muse, mutect2, varscan2
- LAMA2 | c.6598C>T p.R2200C | Missense Mutation (SNP) | VAF 95/170 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs568648664, COSV70346607; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMB3 | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 226/364 reads (62%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs922467680; called by muse, mutect2, varscan2
- LMTK2 | c.4148C>T p.A1383V | Missense Mutation (SNP) | VAF 105/243 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.137); catalogued as rs775353414, COSV51995511; called by muse, mutect2, varscan2
- LMX1A | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 204/310 reads (66%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as rs559035208, COSV54224377; called by muse, mutect2, varscan2
- LOXHD1 | c.3392A>G p.D1131G | Missense Mutation (SNP) | VAF 190/343 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); catalogued as rs1022606346; called by muse, mutect2, varscan2
- LRIG1 | c.2882C>T p.A961V | Missense Mutation (SNP) | VAF 314/543 reads (58%) | SIFT tolerated (0.37); PolyPhen benign (0.036); catalogued as rs191578336; called by muse, mutect2, varscan2
- LRP8 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 326/542 reads (60%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs1364119120, COSV100036263; called by muse, mutect2, varscan2
- LY9 | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 162/301 reads (54%) | SIFT tolerated (0.64); PolyPhen benign (0.01); catalogued as rs199601456, COSV54433623; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1496C>T p.P499L | Missense Mutation (SNP) | VAF 175/298 reads (59%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV50496558; called by muse, mutect2, varscan2
- MCOLN1 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 210/581 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.311); catalogued as rs773382513, COSV51175221; called by muse, mutect2, varscan2
- MYO15A | c.5809C>T p.R1937C | Missense Mutation (SNP) | VAF 173/290 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749465098, CM1513031, COSV52757841; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO1D | c.1886G>A p.R629H | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1262527589, COSV59016625; called by muse, mutect2
- NBAS | c.5129C>T p.T1710M | Missense Mutation (SNP) | VAF 99/165 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as rs369271997; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEB | c.5150G>A p.R1717H | Missense Mutation (SNP) | VAF 162/261 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747091795, COSV50836162; called by muse, mutect2, varscan2
- NEMF | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 53/91 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs141547876; called by muse, mutect2, varscan2
- OR10Z1 | c.16G>A p.V6I | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs368213130; called by muse, mutect2, varscan2
- PAPLN | c.2485G>A p.G829S (on ENST00000554301; = p.G802S on NM_173462.4) | Missense Mutation (SNP) | VAF 50/80 reads (63%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs756661474; called by muse, mutect2, varscan2
- PCDHA4 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 25/515 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.798); catalogued as rs1554124539, COSV63547367; called by muse, mutect2
- PHB | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 110/156 reads (71%) | SIFT tolerated (0.05); PolyPhen benign (0.063); catalogued as rs757906969, COSV100303094, COSV55930873; called by muse, mutect2, varscan2
- PRDM16 | c.1355C>T p.T452M | Missense Mutation (SNP) | VAF 172/275 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as rs781154573; called by muse, mutect2, varscan2
- PRICKLE2 | c.1789C>T p.R597W (on ENST00000295902; = p.R541W on NM_198859.4) | Missense Mutation (SNP) | VAF 103/164 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs372400638, COSV99897969; called by muse, mutect2, varscan2
- PTPN7 | c.203G>A p.R68Q (on ENST00000495688; = p.R107Q on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 150/266 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.097); catalogued as rs749074735, COSV100459565, COSV100459785, COSV58313390; called by muse, mutect2, varscan2
- PTPRZ1 | c.3416C>T p.S1139L | Missense Mutation (SNP) | VAF 71/169 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs201059235; called by muse, mutect2, varscan2
- RASIP1 | c.2203G>A p.A735T | Missense Mutation (SNP) | VAF 216/402 reads (54%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs202046985; called by muse, varscan2
- RBFA | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 97/178 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138368263; called by muse, mutect2, varscan2
- RBMXL3 | c.1265G>A p.R422H | Missense Mutation (SNP) | VAF 218/303 reads (72%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); catalogued as rs1556557964, COSV100407923; called by muse, mutect2, varscan2
- REV3L | c.8144G>A p.R2715Q | Missense Mutation (SNP) | VAF 129/225 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs141338934; called by muse, mutect2, varscan2
- RPP40 | c.689C>T p.T230M | Missense Mutation (SNP) | VAF 245/399 reads (61%) | SIFT deleterious (0.05); PolyPhen benign (0.175); catalogued as rs558469947; called by muse, mutect2, varscan2
- RRM1 | c.1417G>A p.V473I | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.003); catalogued as rs753350029, COSV56165162; called by muse, mutect2, varscan2
- SARDH | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 180/310 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1234578264, COSV53833758; called by muse, mutect2, varscan2
- SCML4 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 166/239 reads (69%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.457); catalogued as rs775844019, COSV64635149; called by muse, mutect2, varscan2
- SFSWAP | c.1366G>A p.V456I | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs150417857; called by muse, mutect2, varscan2
- SHANK1 | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 176/293 reads (60%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.874); catalogued as COSV53251738; called by muse, mutect2, varscan2
- SIPA1 | c.1504G>A p.D502N | Missense Mutation (SNP) | VAF 258/423 reads (61%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.776); catalogued as rs748683552; called by muse, mutect2, varscan2
- SLC26A6 | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 51/93 reads (55%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs942045657, COSV56572558; called by muse, mutect2, varscan2
- SLC26A9 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 60/104 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs901827570, COSV100536359, COSV61601447, COSV61604671; called by muse, mutect2, varscan2
- SLC44A2 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 218/358 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1355261894, COSV59836055, COSV59838669; called by muse, mutect2, varscan2
- SLC4A9 | c.1438C>T p.R480C (on ENST00000507527 / NM_001258428.2; = p.R456C on NM_031467.3) | Missense Mutation (SNP) | VAF 49/72 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774917090, COSV50187232; called by muse, mutect2, varscan2
- SLC8B1 | c.1304C>T p.A435V | Missense Mutation (SNP) | VAF 139/238 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as rs748038619, COSV52527222; called by muse, mutect2, varscan2
- SMARCA2 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 294/471 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1345457262, COSV61804497; called by muse, mutect2, varscan2
- SMARCAL1 | c.2479G>A p.V827M | Missense Mutation (SNP) | VAF 303/527 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs146849562; called by muse, mutect2, varscan2
- SNCAIP | c.2192G>A p.R731H | Missense Mutation (SNP) | VAF 230/397 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.732); catalogued as rs146515227; called by muse, mutect2, varscan2
- SPRR2E | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 134/271 reads (49%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.694); catalogued as rs146373267; called by muse, mutect2, varscan2
- SPTA1 | c.5204G>A p.R1735Q | Missense Mutation (SNP) | VAF 202/335 reads (60%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs374379436; called by muse, mutect2, varscan2
- SPTB | c.2555C>T p.T852M | Missense Mutation (SNP) | VAF 185/299 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs753867736, COSV67633724; called by muse, mutect2, varscan2
- ST6GALNAC4 | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 68/280 reads (24%) | PolyPhen benign (0.026); catalogued as rs749985360, COSV59130203; called by muse, mutect2, varscan2
- ST6GALNAC6 | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 196/339 reads (58%) | PolyPhen possibly damaging (0.828); catalogued as rs149685852, COSV99398556; called by muse, mutect2, varscan2
- ST8SIA5 | c.1109C>T p.T370M | Missense Mutation (SNP) | VAF 38/79 reads (48%) | PolyPhen probably damaging (1); catalogued as rs780097367; called by muse, mutect2, varscan2
- TCOF1 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 196/340 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.046); catalogued as rs574602226; called by muse, mutect2, varscan2
- TEKT5 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 80/132 reads (61%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as rs770636642, COSV99296199; called by muse, mutect2, varscan2
- TG | c.8203G>A p.G2735R | Missense Mutation (SNP) | VAF 312/532 reads (59%) | SIFT tolerated (0.14); PolyPhen benign (0.243); catalogued as rs777891366, COSV55070721; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TGFBR3 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 186/326 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs148843052; called by muse, mutect2, varscan2
- TMED2 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as rs773104041, COSV51628724; called by muse, mutect2, varscan2
- TMEM132E | c.1826G>A p.R609Q (on ENST00000321639; = p.R699Q on NM_001304438.2) | Missense Mutation (SNP) | VAF 121/196 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs776685272, COSV58699465, COSV58699630; called by muse, mutect2, varscan2
- TNRC18 | c.2624G>A p.R875Q | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.994); catalogued as rs868315817; called by muse, mutect2, varscan2
- TOR2A | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs374370419; called by muse, mutect2, varscan2
- TRIM38 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 102/183 reads (56%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as rs780755815, COSV62641836; called by muse, mutect2, varscan2
- TRIM64B | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 269/871 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs761818237, COSV61694147; called by muse, mutect2, varscan2
- TSC1 | c.1585G>A p.A529T | Missense Mutation (SNP) | VAF 126/195 reads (65%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs751125011, COSV100051241; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- TSPAN17 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 149/216 reads (69%) | SIFT tolerated (0.57); PolyPhen benign (0.071); catalogued as rs574457257; called by muse, mutect2, varscan2
- TSPAN6 | c.328G>A p.V110I | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.107); catalogued as rs764529766; called by muse, mutect2, varscan2
- TTC21B | c.2816G>A p.R939Q | Missense Mutation (SNP) | VAF 24/496 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs751382210; called by muse, mutect2
- TTN | c.83950G>A p.V27984I (on ENST00000591111; = p.V20560I on NM_003319.4) | Missense Mutation (SNP) | VAF 75/242 reads (31%) | PolyPhen benign (0.129); catalogued as rs764499992; called by muse, mutect2, varscan2
- TUSC2 | c.274G>A p.V92M | Missense Mutation (SNP) | VAF 106/190 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.428); catalogued as rs369516637; called by muse, mutect2, varscan2
- UBALD1 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 12/13 reads (92%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.29); catalogued as rs371867321; called by muse, varscan2
- UGT1A4 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 225/415 reads (54%) | SIFT tolerated (0.92); PolyPhen benign (0.007); catalogued as COSV59382379; called by muse, mutect2, varscan2
- UNC80 | c.4949C>T p.T1650M | Missense Mutation (SNP) | VAF 148/253 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs1337709618, COSV55912829; called by muse, mutect2, varscan2
- USP42 | c.3922C>T p.R1308C | Missense Mutation (SNP) | VAF 76/181 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.401); catalogued as rs530309193, COSV60358668; called by muse, mutect2, varscan2
- UTP14C | c.1937G>A p.R646H | Missense Mutation (SNP) | VAF 193/292 reads (66%) | SIFT deleterious (0.03); PolyPhen benign (0.364); catalogued as rs1325643858; called by muse, mutect2, varscan2
- VASH1 | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 64/121 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746572157; called by muse, mutect2, varscan2
- VIPR1 | c.1282G>A p.A428T | Missense Mutation (SNP) | VAF 279/472 reads (59%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV100285805; called by muse, mutect2, varscan2
- VPS4A | c.970C>T p.R324W | Missense Mutation (SNP) | VAF 48/644 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as rs747774322; called by muse, mutect2
- VWA1 | c.493G>A p.V165M | Missense Mutation (SNP) | VAF 161/302 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs745450359, COSV58599789; called by muse, mutect2, varscan2
- VWF | c.7440C>T p.G2480= | Splice Region (SNP) | VAF 289/800 reads (36%) | catalogued as rs1172235742; called by muse, mutect2, varscan2
- ZBED4 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs142948522; called by muse, mutect2, varscan2
- ZFHX4 | c.6391C>T p.R2131C | Missense Mutation (SNP) | VAF 79/118 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1427332152; called by muse, mutect2, varscan2
- ZNF324B | c.988C>T p.R330W | Missense Mutation (SNP) | VAF 85/226 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs764179439; called by muse, mutect2, varscan2
- ZNF385D | c.121C>A p.L41I | Missense Mutation (SNP) | VAF 9/208 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.899); catalogued as COSV55754230, COSV55770534; called by muse, mutect2
- ZNF469 | c.8701G>A p.E2901K (on ENST00000437464; = p.E2929K on NM_001367624.2) | Missense Mutation (SNP) | VAF 220/365 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs578166707, COSV71258243; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF845 | c.2195C>T p.S732L | Missense Mutation (SNP) | VAF 52/206 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as rs1568743439; called by muse, mutect2, varscan2
- ACTRT1 | c.699C>A p.S233R | Missense Mutation (SNP) | VAF 166/219 reads (76%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAMTSL3 | c.318-1G>A p.X106_splice | Splice Site (SNP) | VAF 42/66 reads (64%) | called by muse, mutect2, varscan2
- ADGRE5 | c.889A>G p.T297A (on ENST00000242786 / NM_078481.4; = p.T204A on NM_001784.5) | Missense Mutation (SNP) | VAF 140/238 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- ARHGEF33 | c.1249C>T p.H417Y | Missense Mutation (SNP) | VAF 57/89 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARID5B | c.906dup p.V303Sfs*4 | Frame Shift Ins (INS) | VAF 99/208 reads (48%) | called by mutect2, pindel, varscan2
- BAIAP2 | c.1043C>T p.T348I | Missense Mutation (SNP) | VAF 193/306 reads (63%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- BARX2 | c.185C>T p.T62M | Missense Mutation (SNP) | VAF 77/129 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- CHST2 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- COL4A2 | c.4198C>T p.Q1400* | Nonsense Mutation (SNP) | VAF 81/125 reads (65%) | called by muse, mutect2, varscan2
- CPAMD8 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 6/10 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); called by muse, varscan2
- CRIP2 | c.32C>T p.T11I | Missense Mutation (SNP) | VAF 203/327 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CSMD2 | c.5255C>T p.S1752L | Missense Mutation (SNP) | VAF 347/586 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- DGLUCY | c.1712T>C p.M571T | Missense Mutation (SNP) | VAF 74/115 reads (64%) | SIFT tolerated (0.11); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- DNAH10 | c.9766C>T p.R3256W (on ENST00000409039; = p.R3195W on NM_207437.3) | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- DSCAM | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 82/133 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DTX1 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 12/290 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.103); called by muse, mutect2
- EDN3 | c.620del p.A207Vfs*2 (on ENST00000337938 / NM_001302455.2; = p.L219Ffs*59 on NM_207032.3) | Frame Shift Del (DEL) | VAF 247/535 reads (46%) | called by mutect2, pindel, varscan2
- ELFN1 | c.2157del p.P721Hfs*40 | Frame Shift Del (DEL) | VAF 176/540 reads (33%) | called by mutect2, pindel, varscan2
- GBF1 | c.4385G>A p.R1462Q (on ENST00000369983 / NM_001377137.1; = p.R1461Q on NM_004193.3) | Missense Mutation (SNP) | VAF 234/401 reads (58%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- IMMT | c.1817A>G p.N606S | Missense Mutation (SNP) | VAF 116/178 reads (65%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KIAA1755 | c.2255del p.P752Lfs*11 | Frame Shift Del (DEL) | VAF 70/141 reads (50%) | called by mutect2, pindel, varscan2
- MED12 | c.1087A>T p.S363C | Missense Mutation (SNP) | VAF 133/182 reads (73%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- MOCOS | c.258C>G p.S86R | Missense Mutation (SNP) | VAF 240/401 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- NF1 | c.5731_5732del p.I1911* (on ENST00000358273 / NM_001042492.3; = p.I1890* on NM_000267.3) | Frame Shift Del (DEL) | VAF 43/185 reads (23%) | called by mutect2, pindel, varscan2
- NUP205 | c.824T>A p.L275H | Missense Mutation (SNP) | VAF 138/380 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR13C5 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAGE3 | c.338T>A p.V113D | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); called by muse, mutect2, varscan2
- PCDH9 | c.908_909del p.F303Cfs*4 | Frame Shift Del (DEL) | VAF 53/96 reads (55%) | called by mutect2, pindel, varscan2
- PCDHB16 | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLAG1 | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- PTGDS | c.308G>A p.G103D | Missense Mutation (SNP) | VAF 97/170 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPN4 | c.361T>C p.Y121H | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- RAI1 | c.5111G>A p.G1704E | Missense Mutation (SNP) | VAF 393/673 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEC62 | c.122G>A p.G41D | Missense Mutation (SNP) | VAF 68/141 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SETD1B | c.1777C>T p.R593W | Missense Mutation (SNP) | VAF 118/198 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- SF3B3 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TENT5C | c.503A>G p.K168R | Missense Mutation (SNP) | VAF 153/246 reads (62%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- TOPAZ1 | c.3019A>T p.S1007C | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ADAMTS13 | c.2067C>T p.A689= | Silent (SNP) | VAF 230/376 reads (61%) | catalogued as rs782806565; called by muse, mutect2, varscan2
- AIMP1 | c.312C>T p.T104= | Silent (SNP) | VAF 60/114 reads (53%) | catalogued as rs201162461, COSV100786163, COSV63638104; called by muse, mutect2, varscan2
- ANK3 | c.4698C>T p.D1566= | Silent (SNP) | VAF 88/138 reads (64%) | catalogued as rs774722301, COSV55043189; called by muse, mutect2, varscan2
- ANKRD9 | c.225G>A p.A75= | Silent (SNP) | VAF 159/255 reads (62%) | catalogued as rs775819051, COSV54601155; called by muse, mutect2, varscan2
- APBB1 | c.111C>T p.N37= | Silent (SNP) | VAF 38/77 reads (49%) | catalogued as rs146256766; called by muse, mutect2, varscan2
- APC2 | c.4134C>T p.P1378= | Silent (SNP) | VAF 105/163 reads (64%) | catalogued as rs966488100; called by muse, mutect2, varscan2
- APOL1 | c.1062C>T p.Y354= | Silent (SNP) | VAF 102/178 reads (57%) | catalogued as rs760511001, COSV59868692; called by muse, mutect2, varscan2
- AQP9 | c.342T>C p.F114= | Silent (SNP) | VAF 109/181 reads (60%) | called by muse, mutect2, varscan2
- ATP13A2 | c.462G>A p.A154= | Silent (SNP) | VAF 325/574 reads (57%) | catalogued as COSV58703908; called by mutect2, varscan2
- BAIAP2 | c.567G>A p.E189= | Silent (SNP) | VAF 139/257 reads (54%) | catalogued as rs763296707; called by muse, mutect2, varscan2
- BSPRY | c.1116C>T p.S372= | Silent (SNP) | VAF 124/208 reads (60%) | catalogued as rs377414171; called by muse, mutect2, varscan2
- BTBD16 | c.486G>A p.T162= | Silent (SNP) | VAF 45/71 reads (63%) | catalogued as rs776344285; called by muse, mutect2, varscan2
- CCDC154 | c.1719G>A p.T573= | Silent (SNP) | VAF 62/93 reads (67%) | catalogued as rs527249031, COSV66736514; called by muse, mutect2, varscan2
- CCDC33 | c.372C>T p.D124= | Silent (SNP) | VAF 112/190 reads (59%) | catalogued as rs890250748; called by muse, mutect2, varscan2
- CD200 | c.744C>T p.T248= (on ENST00000473539 / NM_001004196.3; = p.T223= on NM_005944.7 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 62/89 reads (70%) | catalogued as rs776155589, COSV59865164; called by muse, mutect2, varscan2
- CDH20 | c.2310G>A p.S770= | Silent (SNP) | VAF 18/246 reads (7%) | catalogued as rs369949747; called by muse, mutect2
- CLDN15 | c.414C>T p.Y138= | Silent (SNP) | VAF 199/569 reads (35%) | catalogued as rs755988993; called by muse, mutect2, varscan2
- CLPTM1 | c.1866G>A p.T622= | Silent (SNP) | VAF 89/134 reads (66%) | catalogued as rs1002440167, COSV100493587; called by muse, mutect2, varscan2
- CNNM2 | c.2532C>T p.D844= | Silent (SNP) | VAF 232/419 reads (55%) | catalogued as rs569125352, COSV63998126; called by muse, mutect2, varscan2
- COL5A3 | c.1839G>A p.T613= | Silent (SNP) | VAF 95/172 reads (55%) | catalogued as rs538680453; called by muse, mutect2, varscan2
- CYYR1 | c.279G>A p.A93= | Silent (SNP) | VAF 109/195 reads (56%) | catalogued as rs775962889, COSV54836322; called by muse, mutect2, varscan2
- DIS3L2 | c.2103G>A p.S701= | Silent (SNP) | VAF 19/209 reads (9%) | catalogued as rs766200831, COSV99806825; called by muse, mutect2, varscan2
- DNAH11 | c.6018G>A p.P2006= | Silent (SNP) | VAF 112/341 reads (33%) | catalogued as rs368842512; ClinVar: likely benign; called by muse, mutect2, varscan2
- EPRS1 | c.3942A>G p.A1314= | Silent (SNP) | VAF 42/75 reads (56%) | called by muse, mutect2, varscan2
- EXOC3 | c.1146G>A p.T382= | Silent (SNP) | VAF 188/286 reads (66%) | catalogued as rs773259161, COSV59268435; called by muse, mutect2, varscan2
- FAM53A | c.348G>A p.P116= | Silent (SNP) | VAF 39/64 reads (61%) | catalogued as rs373370972; called by muse, mutect2, varscan2
- FBN2 | c.3420C>T p.C1140= | Silent (SNP) | VAF 247/437 reads (57%) | catalogued as rs756541654, COSV52490627; ClinVar: likely benign; called by muse, mutect2, varscan2
- FBN3 | c.4101C>T p.A1367= | Silent (SNP) | VAF 35/60 reads (58%) | catalogued as rs562690243; called by muse, mutect2, varscan2
- FCGBP | c.8028C>T p.H2676= | Silent (SNP) | VAF 38/950 reads (4%) | catalogued as rs1220464723; called by muse, mutect2
- FRMD1 | c.57G>A p.T19= | Silent (SNP) | VAF 64/114 reads (56%) | catalogued as rs752747508; called by muse, mutect2, varscan2
- GADL1 | c.621G>A p.S207= | Silent (SNP) | VAF 66/129 reads (51%) | catalogued as rs766955427, COSV56976577; called by muse, mutect2, varscan2
- GGA3 | c.186G>A p.A62= | Silent (SNP) | VAF 186/317 reads (59%) | catalogued as rs751018627, COSV55457274, COSV99822036; called by muse, mutect2, varscan2
- GOLGA3 | c.882C>T p.D294= | Silent (SNP) | VAF 65/94 reads (69%) | catalogued as rs143511800, COSV52630191; called by muse, mutect2, varscan2
- GUCY2D | c.2259C>T p.P753= | Silent (SNP) | VAF 53/569 reads (9%) | catalogued as rs1240523035, COSV99644144; called by muse, mutect2
- HAUS4 | c.663G>A p.K221= | Silent (SNP) | VAF 100/200 reads (50%) | catalogued as COSV99246894; called by muse, mutect2, varscan2
- HDGFL1 | c.558G>A p.A186= | Silent (SNP) | VAF 48/85 reads (56%) | catalogued as rs765403858; called by muse, mutect2, varscan2
- HMCN1 | c.13599C>T p.S4533= | Silent (SNP) | VAF 144/254 reads (57%) | catalogued as COSV99627632; called by muse, mutect2, varscan2
- HYDIN | c.1317C>T p.C439= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs544937612, COSV55504538; called by mutect2, varscan2
- IFI6 | c.255C>T p.G85= | Silent (SNP) | VAF 120/203 reads (59%) | catalogued as rs1186172932; called by muse, mutect2, varscan2
- IFNE | c.531C>T p.F177= | Silent (SNP) | VAF 93/144 reads (65%) | catalogued as COSV104413416; called by muse, mutect2, varscan2
- IMPA2 | c.561G>C p.L187= | Silent (SNP) | VAF 30/171 reads (18%) | catalogued as COSV52321136; called by muse, mutect2, varscan2
- ITPR1 | c.2760C>T p.N920= (on ENST00000354582; = p.N905= on NM_002222.7) | Silent (SNP) | VAF 69/117 reads (59%) | catalogued as rs764544951; called by muse, mutect2, varscan2
- KLF5 | c.468G>A p.P156= | Silent (SNP) | VAF 228/383 reads (60%) | catalogued as rs780125627, COSV66613554; called by muse, mutect2, varscan2
- LRGUK | c.1407C>T p.D469= | Silent (SNP) | VAF 60/160 reads (38%) | catalogued as rs1224860283, COSV53639802; called by muse, mutect2, varscan2
- MINAR1 | c.294C>T p.G98= | Silent (SNP) | VAF 118/217 reads (54%) | catalogued as rs138901860; called by muse, mutect2, varscan2
- MTBP | c.1767C>T p.G589= | Silent (SNP) | VAF 72/121 reads (60%) | called by muse, mutect2, varscan2
- MUC17 | c.954G>A p.T318= | Silent (SNP) | VAF 53/124 reads (43%) | catalogued as rs775661782, COSV60285545; called by muse, mutect2, varscan2
- MUC17 | c.4461C>T p.V1487= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as COSV60288918; called by muse, varscan2
- MYO15A | c.2379G>A p.A793= | Silent (SNP) | VAF 84/146 reads (58%) | catalogued as COSV52754796; called by muse, mutect2, varscan2
- MYOM2 | c.2517C>T p.S839= | Silent (SNP) | VAF 148/292 reads (51%) | catalogued as rs369969429, COSV50709387; called by muse, mutect2, varscan2
- NCKAP5L | c.2982G>A p.R994= | Silent (SNP) | VAF 21/44 reads (48%) | called by muse, mutect2, varscan2
- NDST1 | c.1290G>A p.A430= | Silent (SNP) | VAF 255/403 reads (63%) | catalogued as rs1561601763, COSV55788581, COSV55791635; called by muse, mutect2, varscan2
- NEURL1B | c.378G>A p.P126= | Silent (SNP) | VAF 67/112 reads (60%) | called by muse, mutect2, varscan2
- OOEP | c.180C>T p.D60= | Silent (SNP) | VAF 86/126 reads (68%) | catalogued as rs762305836; called by muse, mutect2
- OR10J1 | c.774C>T p.Y258= | Silent (SNP) | VAF 104/185 reads (56%) | catalogued as COSV71129272; called by muse, mutect2, varscan2
- PCDH8 | c.1965G>A p.Q655= | Silent (SNP) | VAF 160/245 reads (65%) | called by muse, mutect2, varscan2
- PKM | c.6G>A p.S2= | Silent (SNP) | VAF 54/80 reads (68%) | catalogued as rs764776324, COSV58787412; called by muse, mutect2, varscan2
- PKN1 | c.2472C>T p.F824= | Silent (SNP) | VAF 62/230 reads (27%) | catalogued as rs758955037, COSV52874419; called by muse, mutect2, varscan2
- PPIL1 | c.465C>T p.D155= | Silent (SNP) | VAF 183/308 reads (59%) | catalogued as rs758011110, COSV65472845; called by muse, mutect2, varscan2
- PPP1R2B | c.84G>A p.S28= | Silent (SNP) | VAF 29/614 reads (5%) | catalogued as rs778681228, COSV70372913; called by muse, mutect2
- PRDM16 | c.1479G>A p.P493= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as rs766499922; called by muse, mutect2, varscan2
- PRDM2 | c.4554G>A p.A1518= | Silent (SNP) | VAF 102/143 reads (71%) | catalogued as rs200943058, COSV52451144; called by muse, mutect2, varscan2
- PRKCE | c.912C>T p.A304= | Silent (SNP) | VAF 138/256 reads (54%) | catalogued as rs767618652; called by muse, mutect2, varscan2
- PSD2 | c.1020C>T p.N340= | Silent (SNP) | VAF 207/364 reads (57%) | catalogued as rs142589356; called by muse, mutect2, varscan2
- PTPRF | c.1461C>T p.R487= | Silent (SNP) | VAF 199/317 reads (63%) | catalogued as rs562568662; called by muse, mutect2, varscan2
- PTPRF | c.1821C>T p.S607= | Silent (SNP) | VAF 109/151 reads (72%) | catalogued as rs1318858989, COSV63443891; called by muse, mutect2, varscan2
- RRP12 | c.2529C>T p.I843= | Silent (SNP) | VAF 95/161 reads (59%) | catalogued as rs543138148; called by muse, mutect2, varscan2
- SCYL3 | c.1893C>T p.D631= (on ENST00000367770; = p.D577= on NM_020423.7) | Silent (SNP) | VAF 36/57 reads (63%) | catalogued as rs766036301; called by muse, mutect2, varscan2
- SERPINF2 | c.117G>A p.P39= | Silent (SNP) | VAF 213/366 reads (58%) | catalogued as rs139885061; called by muse, mutect2, varscan2
- SHANK3 | c.3003G>A p.A1001= | Silent (SNP) | VAF 49/68 reads (72%) | called by muse, mutect2, varscan2
- SLC22A31 | c.903C>T p.D301= | Silent (SNP) | VAF 36/356 reads (10%) | catalogued as rs922755416, COSV57023327; called by muse, mutect2
- SLC6A11 | c.1890G>A p.T630= | Silent (SNP) | VAF 35/62 reads (56%) | catalogued as rs770168883, COSV99595220; called by muse, mutect2, varscan2
- SLIT2 | c.2613C>T p.S871= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as rs754922750, COSV99885513; called by muse, mutect2, varscan2
- SPTBN1 | c.3657C>T p.D1219= | Silent (SNP) | VAF 187/305 reads (61%) | catalogued as rs567753600, COSV61690905; called by muse, mutect2, varscan2
- SREK1 | c.165C>T p.N55= | Silent (SNP) | VAF 49/119 reads (41%) | catalogued as rs538442754, COSV52334764; called by muse, mutect2, varscan2
- STAT5B | c.2097C>T p.Y699= | Silent (SNP) | VAF 238/425 reads (56%) | catalogued as rs369507540; ClinVar: likely benign; called by muse, mutect2, varscan2
- TBL2 | c.414C>T p.H138= | Silent (SNP) | VAF 153/383 reads (40%) | catalogued as rs369863389; called by muse, mutect2, varscan2
- TGM6 | c.537C>T p.Y179= | Silent (SNP) | VAF 152/256 reads (59%) | catalogued as rs140070681; ClinVar: benign; called by muse, mutect2, varscan2
- THOC1 | c.645C>T p.G215= | Silent (SNP) | VAF 45/83 reads (54%) | catalogued as rs563042825; called by muse, mutect2, varscan2
- THOC6 | c.777G>A p.A259= | Silent (SNP) | VAF 218/384 reads (57%) | catalogued as rs149452461; called by muse, mutect2, varscan2
- WDR24 | c.2394C>T p.I798= (on ENST00000248142; = p.I668= on NM_032259.4) | Silent (SNP) | VAF 75/118 reads (64%) | catalogued as rs1352322091; called by muse, mutect2, varscan2
- ZFAND2B | c.516C>T p.T172= | Silent (SNP) | VAF 114/212 reads (54%) | called by muse, mutect2, varscan2
- ZNF469 | c.1932G>A p.T644= | Silent (SNP) | VAF 202/346 reads (58%) | catalogued as rs539996728; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF536 | c.1908C>T p.C636= | Silent (SNP) | VAF 165/294 reads (56%) | catalogued as rs763902544, COSV100835870, COSV62822641; called by muse, mutect2, varscan2
- ZNF541 | c.2160C>T p.A720= | Silent (SNP) | VAF 296/447 reads (66%) | catalogued as rs1369798695; called by muse, mutect2, varscan2
- ZNF783 | c.102G>A p.S34= | Silent (SNP) | VAF 98/247 reads (40%) | catalogued as rs765442197; called by muse, mutect2, varscan2
- ZSCAN26 | c.363C>T p.D121= | Silent (SNP) | VAF 59/100 reads (59%) | catalogued as rs920026866, COSV100348429; called by muse, mutect2, varscan2
- ANKRD20A5P | n.39G>A | RNA (SNP) | VAF 11/340 reads (3%) | called by muse, mutect2
- ARL2 | c.339+204C>T | Intron (SNP) | VAF 70/112 reads (63%) | catalogued as rs945601754; called by muse, mutect2, varscan2
- C3orf35 | n.1268G>A | RNA (SNP) | VAF 135/229 reads (59%) | called by muse, mutect2, varscan2
- CCZ1 | c.439-22del | Intron (DEL) | VAF 18/34 reads (53%) | catalogued as rs777840474; called by mutect2, varscan2
- CD81 | c.649-44C>T | Intron (SNP) | VAF 263/441 reads (60%) | catalogued as rs773369922; called by muse, mutect2, varscan2
- CLEC1B | c.545+95T>C | Intron (SNP) | VAF 76/230 reads (33%) | called by muse, mutect2, varscan2
- DHRS4 | chr14:23970268 C>T | 3'Flank (SNP) | VAF 10/73 reads (14%) | catalogued as rs1367960727; called by muse, mutect2, varscan2
- DNM2 | c.1493+32G>A | Intron (SNP) | VAF 171/296 reads (58%) | catalogued as rs199554818; called by muse, mutect2, varscan2
- EFHD2 | c.592-615C>T | Intron (SNP) | VAF 164/294 reads (56%) | catalogued as rs1054363025; called by muse, mutect2, varscan2
- EPHB6 | c.1918+44G>A | Intron (SNP) | VAF 162/428 reads (38%) | called by muse, mutect2, varscan2
- FOXP2 | c.*2977C>T | 3'UTR (SNP) | VAF 34/109 reads (31%) | catalogued as rs887844453; called by muse, mutect2, varscan2
- KCNQ2 | c.1247+72C>T | Intron (SNP) | VAF 32/66 reads (48%) | catalogued as rs1417263244; called by muse, mutect2
- MOB1A | c.-34C>T | 5'UTR (SNP) | VAF 9/16 reads (56%) | called by muse, mutect2
- MPPED1 | c.-60G>A | 5'UTR (SNP) | VAF 67/101 reads (66%) | catalogued as rs755292255; called by muse, mutect2, varscan2
- NXF5 | n.1531G>A | RNA (SNP) | VAF 149/196 reads (76%) | catalogued as rs373035757, COSV53793865; called by muse, mutect2, varscan2
- OSGIN1 | n.1393G>A | RNA (SNP) | VAF 31/38 reads (82%) | catalogued as rs369392211; called by muse, mutect2, varscan2
- PACRG | c.613+101508C>T | Intron (SNP) | VAF 123/194 reads (63%) | catalogued as rs76650950; called by muse, mutect2, varscan2
- PLOD1 | c.77-3337C>T | Intron (SNP) | VAF 82/131 reads (63%) | called by muse, mutect2, varscan2
- PRR12 | chr19:49594718 C>T | 5'Flank (SNP) | VAF 44/353 reads (12%) | catalogued as rs1432300592; called by muse, mutect2, varscan2
- RFXANK | c.632-179G>A | Intron (SNP) | VAF 193/339 reads (57%) | catalogued as rs367751499; called by muse, mutect2, varscan2
- RNF216 | c.67+531G>A | Intron (SNP) | VAF 37/175 reads (21%) | catalogued as rs7794953; called by muse, mutect2, varscan2
- RUNX1 | c.*28C>T | 3'UTR (SNP) | VAF 46/74 reads (62%) | called by muse, mutect2, varscan2
- SPAG6 | c.121+82T>A | Intron (SNP) | VAF 17/274 reads (6%) | called by muse, mutect2
- STXBP2 | c.1356+35G>A | Intron (SNP) | VAF 76/115 reads (66%) | called by muse, mutect2, varscan2
- TNNI2 | c.186+14C>T | Intron (SNP) | VAF 227/369 reads (62%) | called by muse, mutect2, varscan2
- TRIO | c.7632+783G>A | Intron (SNP) | VAF 163/261 reads (62%) | catalogued as rs777363551, COSV59992024; called by muse, mutect2, varscan2
- ZNF778 | c.*4587G>A | 3'UTR (SNP) | VAF 302/748 reads (40%) | catalogued as rs79962203; called by muse, varscan2
- ZNF778 | c.*4702G>A | 3'UTR (SNP) | VAF 242/1327 reads (18%) | called by muse, varscan2
